Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23T, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23T-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

y/o female with right retroperitoneal mass from subhepatic to mid pelvis.

Specimens Submitted:

- 1: SP: Right colon and right retroperitoneal mass
- 2: SP: Subcutaneous fat
- 3: SP: Uterine mass
- 4: SP: Right ovarian cyst

DIAGNOSIS:

1. RIGHT COLON AND RETROPERITONEAL MASS; PARTIAL COLECTOMY AND MASS

EXCISION:

- DEDIFFERENTIATED LIPOSARCOMA
- SIZE: 30 X 29 X 11 CM.
- NECROSIS: < 10% OF THE ENTIRE TUMOR.
- MARGINS STATUS:
- TUMOR EXTENDS INKED SOFT TISSUE SURFACES. (SEE NOTE.)
- THE PROXIMAL AND DISTAL INTESTINAL MUCOSAL MARGINS ARE FREE OF

TUMOR.

- COLONIC MUCOSA, TERMINAL ILEAL MUCOSA AND APPENDIX ARE UNREMARKABLE.

NOTE: THE LOW GRADE WELL DIFFERENTIATED ADIPOCYTIC COMPONENT OF THE LIPOSARCOMA

EXTENDS TO INKED SOFT TISSUE SURFACES. NECROSIS IS LIMITED TO THE HIGH GRADE SPINDLE CELL TUMOR COMPONENT.

2. SUBCUTANEOUS FAT; EXCISION:

- GROSSLY UNREMARKABLE ADIPOSE TISSUE, ENTIRELY SUBMITTED TO TPS.

3. UTERINE MASS; EXCISION:

- LEIOMYOMA AND PORTION OF BENIGN ENDOMETRIUM.
- BENIGN SEROSAL CYST.

4. OVARIAN CYST, RIGHT; OOPHORECTOMY:

- CORPUS LUTEUM CYST.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF

** Continued on next page **

1CD-0-3

Dedifferentiated liposarcoma

8858/3

Site: Retroperitoneum C48.0

in 4/2/11

[page 2 of 4]
----- Page 2 of 4
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received the fresh, labeled "right colon and right retroperitoneal mass" and consists of a large lobulated and soft yellow mass measuring 30 x 29 X 11 cm. There is a thin fibrous membrane surrounding the mass. A segment of right colon and terminal ileum is loosely attached to the mass. The right colon measures 17 cm in length and the terminal ileum measures 5 cm in length. The distal colon margin measures 6 cm in circumference and the terminal ileum margin measures 4 m in circumference. A grossly unremarkable appendix is identified measuring 4 x 0.5 cm. Upon opening, the colonic mucosa has a focally hemorrhagic appearance. The mucosa of terminal ileum is grossly unremarkable. No nodule or mass is identified. The large mass grossly does not involve the right colon and terminal ileum. The cut section of the mass shows multilobulated yellow tissue with areas of necrosis and areas of myxoid appearance. Approximately 10% of the tumor is necrotic. Representative sections are submitted.

Summary of sections

PM -- proximal terminal ileum margin
DM -- distal colonic margin
A -- appendix
RM -- random mucosa of colon and terminal ileum
NEC -- necrotic area of the mass
MC -- area of myxoid change of the mass
MM -- mass with inked the margin
SS -- representative sections of the mass
TC tumor with colon

2). The specimen is received fresh, labeled "subcutaneous fat" and consists of a piece of yellow fatty soft tissue measuring 8 x 7 x 2 cm. The specimen is entirely submitted for TPS according to the request by physician. No tissue submitted for cassettes.

3). The specimen is received in formalin, labeled "Uterine mass" and consists of three circumscribed masses of whorled white tan tissue weighing 3 g, and ranging from 0.9 x 0.7 x 0.5 to 1.7 x 1.7 x 1.5 cm. On sectioning, homogeneous white tan whorled tissue

** Continued on next page **

[page 3 of 4]
is identified, with no discrete abnormalities grossly noted. The two smaller pieces show areas of grossly unremarkable pink tan myometrial tissue attached. A thin-walled clear tan fluid filled cyst is also received in the container measuring 1.4 x 1.3 x 0.9 cm, with a pink-tan stalk-like projection attached at the surface measuring 1 x 0.2 x 0.2 cm. Representative sections are submitted.

Summary of sections:

U-undesignated, representative leiomyomata
C-representative cyst

4). The specimen is received in formalin, labeled "Right ovarian cyst" and consists of a partially cystic and partially solid ovary measuring 2.7 x 2.0 x 1.8 cm. The external surface is smooth and pink-tan with no discrete abnormalities grossly noted. The specimen is serially sectioned to reveal a circumscribed solid area of slightly opaque tan-yellow, fleshy, soft tissue measuring 2.7 x 1.5 x 1.2 cm. At the periphery, a hemorrhagic cystic area is noted measuring 1.2 cm in greatest dimension. Representative sections are submitted.

Summary of sections:

U-undesignated

Summary of Sections:

Part 1: SP: Right colon and right retroperitoneal mass

Block	Sect.	Site	PCs
1		A	1
1		DM	1
3		MC	3
15		MM	15
3		NBC	3
1		PM	1
1		RM	1
7		SS	7
2		TC	2

Part 2: SP: Subcutaneous fat

Part 3: SP: Uterine mass

Block	Sect.	Site	PCs
1		c	1

** Continued on next page **

[page 4 of 4]
Part 4: SP: Right ovarian cyst

Block	Sect.	Site	PCs
3	u		0

** End of Report **

IHPAA Discrepancy		/

Source: NCI Genomic Data Commons file 9b7420d8-6252-4e0e-971e-a4d72219e086 (TCGA-DX-A23T.033D9B12-ACB9-47A6-A420-29B88259C17A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).